Somatic mutation profile of tumor specimen TCGA-US-A774-01A (aliquot TCGA-US-A774-01A-21D-A32N-08) from TCGA case TCGA-US-A774, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 76.5 years (27,957 days).
Specimen TCGA-US-A774-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54a1e78c-5dcd-4d7f-aee6-c82165fdd655.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-US-A774-11A (Solid Tissue Normal), aliquot TCGA-US-A774-11A-11D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/602887b0-6c89-404b-9564-b500321b4990

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 12, Silent 7, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPZ | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1183458659, COSV50017033; called by muse, mutect2
- DCLRE1C | c.521A>G p.Y174C (on ENST00000378278 / NM_001350965.2; = p.Y59C on NM_022487.4) | Missense Mutation (SNP) | VAF 48/871 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV100739788; called by muse, mutect2
- H3C11 | c.353T>G p.V118G | Missense Mutation (SNP) | VAF 52/920 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV58899369; called by muse, mutect2
- MUC17 | c.9254C>T p.S3085L | Missense Mutation (SNP) | VAF 80/1511 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs769024651, COSV60282453, COSV60282758; called by muse, mutect2
- MYO18B | c.6812G>A p.G2271D | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as rs1038021282, COSV59128459; called by muse, mutect2
- PLD5 | c.495+1G>A p.X165_splice (on ENST00000442594; = p.X103_splice on NM_001195811.1 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 27/596 reads (5%) | catalogued as COSV59137196; called by muse, mutect2
- PRKCG | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 10/313 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV54725361; called by muse, mutect2
- RBM6 | c.2047A>G p.T683A | Missense Mutation (SNP) | VAF 56/704 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.09); catalogued as COSV56480553; called by muse, mutect2
- RRH | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 31/422 reads (7%) | catalogued as rs568068949, COSV58490567, COSV58490826; called by muse, mutect2
- ST18 | c.3003G>T p.M1001I | Missense Mutation (SNP) | VAF 16/484 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52487661; called by muse, mutect2
- TLK2 | c.2281T>G p.S761A (on ENST00000326270 / NM_001284333.2; = p.S739A on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/354 reads (4%) | SIFT tolerated, low confidence (0.89); PolyPhen possibly damaging (0.746); catalogued as COSV58298034; called by muse, mutect2
- TPO | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.56); catalogued as rs772197481, COSV61097198; called by muse, mutect2
- ZP2 | c.2046C>A p.S682R | Missense Mutation (SNP) | VAF 48/761 reads (6%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.035); catalogued as COSV54812799; called by muse, mutect2
- CHD7 | c.5464G>A p.G1822S | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- DPP4 | c.1395G>A p.A465= | Silent (SNP) | VAF 18/400 reads (5%) | catalogued as COSV62105655; called by muse, mutect2
- EIF2D | c.981G>A p.E327= | Silent (SNP) | VAF 32/500 reads (6%) | catalogued as COSV55112621; called by muse, mutect2
- HMCN1 | c.7038C>T p.H2346= | Silent (SNP) | VAF 23/443 reads (5%) | catalogued as COSV54884810; called by muse, mutect2
- PRKCB | c.585C>T p.Y195= | Silent (SNP) | VAF 41/603 reads (7%) | catalogued as rs543897172, COSV57770453; called by muse, mutect2
- RBMXL2 | c.702G>A p.S234= | Silent (SNP) | VAF 14/183 reads (8%) | catalogued as rs1190794791, COSV60978927; called by muse, mutect2
- TNFRSF19 | c.957C>T p.N319= | Silent (SNP) | VAF 38/721 reads (5%) | catalogued as COSV50311870; called by muse, mutect2
- TTC17 | c.1950A>T p.P650= | Silent (SNP) | VAF 16/256 reads (6%) | catalogued as COSV50006688; called by muse, mutect2
